Somatic mutation profile of tumor specimen C3N-02632-05 (aliquot CPT0182020007) from CPTAC case C3N-02632, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.9 years (21,150 days).
Specimen C3N-02632-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8ee6484-741f-4081-aba4-6f866a447395.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02632-31 (Blood Derived Normal), aliquot CPT0182060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3fb5017-2250-469a-b03e-33c35fe6beb0

The open-access MAF lists 86 somatic variants for this specimen: 62 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Intron 6, Nonsense Mutation 4, Splice Site 2, In Frame Del 2, Splice Region 2, 5'UTR 1, Frame Shift Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 178/581 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 125/462 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- FGFR2 | c.1647T>G p.N549K | Missense Mutation (SNP) | VAF 114/435 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 74/252 reads (29%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC9 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs373792254; called by muse, mutect2, varscan2
- AHNAK | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs759833180; called by muse, mutect2, varscan2
- ARHGEF2 | c.1676G>A p.R559Q (on ENST00000361247 / NM_001162383.2; = p.R531Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1276560238; called by muse, mutect2, varscan2
- BRWD1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753062827; called by muse, mutect2
- BSN | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs200764425; called by muse, mutect2, varscan2
- CADPS | c.3235C>T p.R1079W | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.798); catalogued as COSV51873529; called by muse, mutect2, varscan2
- COL6A3 | c.7259G>A p.R2420Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as rs772077690; called by muse, mutect2, varscan2
- DIP2A | c.2559C>A p.D853E | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336196926; called by muse, mutect2, varscan2
- DMD | c.7034C>T p.S2345F | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100626341; called by muse, mutect2, varscan2
- EPHA1 | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs866192433; called by muse, mutect2, varscan2
- FFAR1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753588393, CM1511235, COSV50049490; called by muse, mutect2, varscan2
- GABRA3 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64794816, COSV64800402; called by muse, mutect2, varscan2
- GPC1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs771344419, COSV50863304; called by muse, mutect2, varscan2
- HOXD8 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as rs1203925855, COSV100496976; called by muse, mutect2, varscan2
- KCNC3 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs146613004; called by muse, mutect2, varscan2
- MBD6 | c.2632C>T p.R878* | Nonsense Mutation (SNP) | VAF 43/143 reads (30%) | catalogued as COSV63074460; called by muse, mutect2, varscan2
- MESP1 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1567141671; called by muse, mutect2, varscan2
- MUC12 | c.10082C>T p.T3361M (on ENST00000379442; = p.T3218M on NM_001164462.1) | Missense Mutation (SNP) | VAF 84/2838 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1292087714; called by muse, mutect2
- MYORG | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as COSV52627518; called by muse, mutect2, varscan2
- OR10Q1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs774025448, COSV100372439, COSV57471231; called by muse, mutect2, varscan2
- OR51E1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760647045, COSV67809478, COSV67810339; called by muse, mutect2, varscan2
- PCDHGA7 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as rs781605513, COSV53945072; called by muse, mutect2, varscan2
- PIK3R1 | c.1735_1740del p.Q579_Y580del (on ENST00000521381 / NM_181523.3; = p.Q309_Y310del on NM_181504.4) | In Frame Del (DEL) | VAF 29/100 reads (29%) | catalogued as rs751582616; called by mutect2, pindel, varscan2
- PPP1R12C | c.1765-5G>A | Splice Region (SNP) | VAF 33/98 reads (34%) | catalogued as rs766427772; called by muse, mutect2, varscan2
- SCN1A | c.5485T>A p.S1829T (on ENST00000303395 / NM_001202435.3; = p.S1818T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57680090; called by muse, mutect2, varscan2
- SMARCA4 | c.3702C>A p.F1234L | Missense Mutation (SNP) | VAF 171/636 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV60791545, COSV60800759; called by muse, mutect2, varscan2
- TAF8 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs775777569, COSV100881003, COSV65895964; called by muse, mutect2, varscan2
- TAS2R60 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs201185058, COSV60332390; called by muse, mutect2, varscan2
- TCF25 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs142679209; called by muse, mutect2, varscan2
- TRABD | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs200288166; called by muse, mutect2, varscan2
- VRK2 | c.1259T>C p.I420T | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs535874314; called by muse, mutect2, varscan2
- ZNF552 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as rs866451794; called by muse, mutect2, varscan2
- ZRSR2 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs746617360, COSV57066997; called by muse, mutect2, varscan2
- ZSCAN29 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT tolerated (0.51); PolyPhen probably damaging (1); catalogued as rs143066980; called by muse, mutect2, varscan2
- ANO7 | c.2481_2483+21del p.X827_splice (on ENST00000274979; = p.X773_splice on NM_001370694.2) | Splice Site (DEL) | VAF 30/118 reads (25%) | called by mutect2, pindel
- ARID1A | c.6745_6746del p.S2249Rfs*28 | Frame Shift Del (DEL) | VAF 30/132 reads (23%) | called by mutect2, pindel, varscan2
- ASXL3 | c.2905C>A p.Q969K | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CACNA1H | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- CD109 | c.4104C>A p.N1368K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CNKSR2 | c.1902dup p.Y635Ifs*9 | Frame Shift Ins (INS) | VAF 16/161 reads (10%) | called by mutect2, pindel, varscan2
- CSMD3 | c.8384C>A p.A2795D (on ENST00000297405 / NM_001363185.1; = p.A2626D on NM_052900.3) | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- DNAH2 | c.12647G>T p.G4216V | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF1AKNMT | c.1709A>G p.D570G (on ENST00000361735 / NM_015935.5; = p.D484G on NM_014955.3) | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- GPHN | c.2020C>T p.H674Y (on ENST00000315266 / NM_001377519.1; = p.H707Y on NM_020806.5) | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HCN1 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MAG | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, varscan2
- NECTIN3 | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OR6J1 | c.534T>A p.C178* | Nonsense Mutation (SNP) | VAF 45/154 reads (29%) | called by muse, mutect2, varscan2
- PCNX1 | c.2236G>A p.V746I | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PNPO | c.287T>C p.M96T | Missense Mutation (SNP) | VAF 157/541 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PTEN | c.451_462del p.A151_F154del | In Frame Del (DEL) | VAF 71/262 reads (27%) | called by mutect2, pindel, varscan2
- PTTG1 | c.370+2_370+3dup p.X124_splice | Splice Site (INS) | VAF 20/102 reads (20%) | called by mutect2, pindel, varscan2
- SLC26A5 | c.735T>C p.Y245= | Splice Region (SNP) | VAF 14/299 reads (5%) | called by muse, mutect2
- STON1-GTF2A1L | c.2606C>G p.P869R | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUCLG2 | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TKT | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TSPAN1 | c.16T>C p.F6L | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX3 | c.2184C>A p.C728* | Nonsense Mutation (SNP) | VAF 60/207 reads (29%) | called by muse, mutect2, varscan2
- ADRA1A | c.1368C>A p.T456= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- ARMH1 | c.1080G>A p.A360= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs1453661590; called by muse, mutect2, varscan2
- BHLHE22 | c.114G>A p.T38= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as rs763590067, COSV58861410; called by muse, mutect2
- CDH19 | c.900G>A p.S300= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs546188565, COSV50955151; called by muse, mutect2, varscan2
- CFAP92 | c.1128C>T p.S376= | Silent (SNP) | VAF 71/246 reads (29%) | catalogued as rs753212116, COSV54047983; called by muse, mutect2, varscan2
- GABRA5 | c.555C>T p.H185= | Silent (SNP) | VAF 68/284 reads (24%) | catalogued as rs140643363, COSV100164876; called by muse, mutect2, varscan2
- GAPDHS | c.948C>T p.D316= | Silent (SNP) | VAF 75/249 reads (30%) | called by muse, mutect2, varscan2
- GTF3C5 | c.1059C>T p.V353= | Silent (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- KCNK15 | c.903C>T p.R301= | Silent (SNP) | VAF 65/200 reads (33%) | called by muse, mutect2, varscan2
- KIAA2026 | c.3195A>G p.V1065= | Silent (SNP) | VAF 82/297 reads (28%) | catalogued as rs771595869; called by muse, mutect2, varscan2
- LRRN4 | c.1299G>A p.T433= | Silent (SNP) | VAF 46/206 reads (22%) | called by muse, mutect2, varscan2
- PAPSS2 | c.1554C>A p.P518= | Silent (SNP) | VAF 106/453 reads (23%) | called by muse, mutect2, varscan2
- PNKP | c.1287G>A p.A429= | Silent (SNP) | VAF 55/489 reads (11%) | catalogued as rs1281900821; called by muse, mutect2, varscan2
- SNED1 | c.2706C>T p.C902= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as rs764256373, COSV60030491; called by muse, mutect2, varscan2
- TIMM44 | c.522G>A p.A174= | Silent (SNP) | VAF 149/546 reads (27%) | catalogued as rs752329160, COSV99564213; called by muse, mutect2, varscan2
- UNC13D | c.147C>T p.P49= | Silent (SNP) | VAF 34/273 reads (12%) | catalogued as rs749672259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRA1 | c.4-3951G>T | Intron (SNP) | VAF 146/592 reads (25%) | called by muse, varscan2
- ADGRA1 | c.4-3950A>T | Intron (SNP) | VAF 147/589 reads (25%) | called by muse, varscan2
- AJAP1 | c.-63G>T | 5'UTR (SNP) | VAF 68/220 reads (31%) | catalogued as rs1440302374, COSV100981479; called by muse, mutect2
- ERCC6L2 | chr9:96020965 A>T | 3'Flank (SNP) | VAF 45/304 reads (15%) | called by muse, mutect2, varscan2
- GCGR | c.658-23C>T | Intron (SNP) | VAF 111/358 reads (31%) | catalogued as rs917647944, COSV68779509; called by muse, mutect2, varscan2
- MVB12A | c.189+19C>T | Intron (SNP) | VAF 16/261 reads (6%) | catalogued as rs1267465734; called by muse, mutect2
- TPM3 | c.567-323T>G | Intron (SNP) | VAF 47/190 reads (25%) | called by muse, mutect2, varscan2
- WDR62 | c.3083-27C>T | Intron (SNP) | VAF 87/298 reads (29%) | catalogued as rs755130081; called by muse, mutect2, varscan2
